Somatic mutation profile of tumor specimen MP2PRT-PARNXI-TMP1-A (aliquot MP2PRT-PARNXI-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARNXI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,497 days).
Specimen MP2PRT-PARNXI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe1fdb22-d281-453d-af9b-fd618e0a6774.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNXI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNXI-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccf51006-447c-477d-bbcb-9308f46de182

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, In Frame Ins 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIA1 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.88); catalogued as rs775760573, COSV53609669; called by muse, mutect2, varscan2
- KIF1A | c.4265C>T p.P1422L (on ENST00000320389 / NM_001379639.1; = p.P1414L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/942 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs867230401, COSV57485849; ClinVar: uncertain significance; called by muse, mutect2
- KLF8 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 192/916 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs748491106; called by muse, mutect2, varscan2
- NAP1L1 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV53875156; called by muse, varscan2
- TMEM179 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 170/774 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs574901720; called by muse, varscan2
- VEGFD | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 119/595 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770666075; called by muse, mutect2, varscan2
- IGKV1D-8 | c.262_263insAGG p.S87_G88insE | In Frame Ins (INS) | VAF 43/194 reads (22%) | called by mutect2, pindel, varscan2
- IGKV2-24 | chr2:89176323 GTGTGAGGAAATTGTGTAGCTTG>CTT | Missense Mutation (DEL) | VAF 28/136 reads (21%) | called by pindel, varscan2*
- OR10A7 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 104/301 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SLIT2 | c.111del p.S37Rfs*26 | Frame Shift Del (DEL) | VAF 168/804 reads (21%) | called by mutect2, pindel*, varscan2
- WNK2 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 113/362 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC57 | c.342C>T p.S114= | Silent (SNP) | VAF 29/445 reads (7%) | called by muse, mutect2
- PRRT2 | c.987C>T p.I329= | Silent (SNP) | VAF 37/643 reads (6%) | catalogued as rs368411419, COSV54884812; called by muse, mutect2
- TMEM271 | c.144C>T p.A48= | Silent (SNP) | VAF 200/888 reads (23%) | called by muse, mutect2, varscan2
- TP73 | c.738G>A p.G246= | Silent (SNP) | VAF 60/312 reads (19%) | called by muse, mutect2
- IGLV4-60 | chr22:22162681 ins TCAACC | 3'Flank (INS) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
